Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4766, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4766-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

with 3.9 x 3 cm hypervascular right renal mass.

Specimens Submitted:

- 1: SP: Right kidney tumor
- 2: SP: Deep margin #2

DIAGNOSIS:

- 1) KIDNEY, RIGHT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 3.9 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- THE SURGICAL MARGIN IS FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 2) MARGIN, DEEP #2; BIOPSY:
- BENIGN RENAL PARENCHYMA.

1) The specimen is received fresh for frozen section consultation labeled, "Right kidney tumor, stitch marks deep margin". It consists of a partial nephrectomy specimen measuring 5.0 x 4.0 x 1.5 cm. The area with the black stitch is inked blue. Cut section the specimen shows a 3.9 x 3.8 x 3.8 cm round, well encapsulated, hemorrhagic orange tumor mass located 0.2 cm from the resected margin. The remainder of the kidney parenchyma is brown tan and unremarkable. Representative sections are frozen. Representative sections are submitted. A sample of the tumor is given to

Summary of sections:

FSCA - frozen section control A (tumor)

FSCB - frozen section control B (margin)

T- tumor

RS -representative section of uninvolved parenchyma

[page 2 of 2]
2) The specimen is received fresh for frozen section consultation labeled, "Deep margin #2". It consists of a piece of gray tan soft tissue measuring 0.4 x 0.2 x 0.2 cm in aggregate. The specimen is entirely frozen.

Summary of sections:
FSC - frozen section control

Summary of Sections:

Part 1: SP: Right kidney tumor [REDACTED]

Block	Sect. Site	PCs
1	fsca	1
1	fsch	1
1	rs	1
4	t	4

Part 2: SP: Deep margin #2 [REDACTED]

Block	Sect. Site	PCs
1	fsc	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1A) FROZEN SECTION DIAGNOSIS: TUMOR: CORTICAL CELL NEOPLASM, FAVOR RENAL CARCINOMA/CLEAR CELL CONVENTIONAL TYPE. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 1B) FROZEN SECTION DIAGNOSIS: MARGIN: BENIGN [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- [REDACTED]

Source: NCI Genomic Data Commons file a772536a-a0e7-45e9-895f-36e27fd976d7 (TCGA-BP-4766.939D54DF-CE2D-4A4D-801D-6D7059AD8ACE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).